Somatic mutation profile of tumor specimen TCGA-BP-4795-01A (aliquot TCGA-BP-4795-01A-02D-1421-08) from TCGA case TCGA-BP-4795, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 74.4 years (27,162 days).
Specimen TCGA-BP-4795-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c10ed9ad-b324-48f6-b330-b9f9934d2bc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4795-11A (Solid Tissue Normal), aliquot TCGA-BP-4795-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67578f81-4733-48e7-ad5d-0f93dec21a1a

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, 3'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREB5 | c.1117G>A p.D373N (on ENST00000357727 / NM_182898.4; = p.D366N on NM_004904.3) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63218297; called by muse, mutect2, varscan2
- DCAF11 | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as rs1390286215, CM143141, COSV58108490; called by muse, mutect2, varscan2
- GRM8 | c.963A>T p.Q321H | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.145); catalogued as COSV58810065; called by muse, mutect2, varscan2
- IDH2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57470830; called by muse, mutect2
- INKA2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as rs1256065444, COSV61877272; called by muse, mutect2
- ITPRID1 | c.859T>C p.F287L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV60071581; called by muse, mutect2, varscan2
- LRRC49 | c.1085A>C p.N362T | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53008787; called by muse, mutect2, varscan2
- MIA2 | c.2326T>A p.S776T | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV54489999; called by muse, mutect2, varscan2
- NAGLU | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV56794289; called by muse, mutect2, varscan2
- PDGFD | c.111C>A p.N37K | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs958505978, COSV56371168; called by muse, mutect2, varscan2
- PTPRH | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV54743506; called by muse, mutect2, varscan2
- SLC4A7 | c.1916G>A p.S639N | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55395530; called by muse, mutect2, varscan2
- TBC1D3B | c.425T>A p.I142N | Missense Mutation (SNP) | VAF 115/788 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- AKAP6 | c.1833A>T p.P611= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as COSV55207395; called by muse, mutect2, varscan2
- KCNH7 | c.2196T>C p.C732= | Silent (SNP) | VAF 58/301 reads (19%) | catalogued as COSV59789553; called by muse, mutect2, varscan2
- KCNN3 | c.429C>T p.S143= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV55213566; called by muse, mutect2, varscan2
- RELCH | c.1362A>G p.P454= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV56883181; called by muse, mutect2, varscan2
- SLC13A4 | c.420C>T p.N140= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1352245961, COSV62460286; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3312T>C p.S1104= | Silent (SNP) | VAF 34/186 reads (18%) | catalogued as rs1317378684, COSV59127579; called by muse, mutect2, varscan2
- TEKT4 | c.555A>G p.A185= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1472729931, COSV54623429; called by muse, mutect2, varscan2
- BVES | c.*1T>A | 3'UTR (SNP) | VAF 44/257 reads (17%) | catalogued as COSV100114668; called by muse, mutect2, varscan2
- SNORD108 | n.50C>G | RNA (SNP) | VAF 18/140 reads (13%) | called by muse, varscan2
- TTI2 | chr8:33513571 G>A | 5'Flank (SNP) | VAF 50/240 reads (21%) | catalogued as rs759898995, COSV100659614; called by muse, mutect2, varscan2
